FM case AD9401 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/04fa4729-f591-46ab-afb3-f70e234a81b4

Male, 78.3 years: Merkel cell carcinoma (ICD-O-3 8247/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
